Gene-level copy-number profile of tumor specimen TCGA-36-2533-01A from TCGA case TCGA-36-2533, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.3 years (20,187 days).
Specimen TCGA-36-2533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.572d0ef3-8c5d-48c8-9129-a2397790f0e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2533-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ca483d4-f560-487f-88a9-994888f7dd97

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 595; copy number 2: 13,461; copy number 3: 14,338; copy number 4: 20,290; copy number 5: 7,924; copy number 6: 2,074; copy number 7: 620; copy number 8: 214; copy number 9: 289; copy number 10: 7; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2533-01A-01D-1043-01): tumor purity 0.73, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 297 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:115,950,511–116,325,062, 1 gene, copy number 9 (within-gene range 6–9): LINC00536.
- chr8:116,289,622–138,497,261, 289 genes, copy number 9–11 (broad region; genes not listed).
- chr18:5,721,812–6,108,382, 5 genes, copy number 10: MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3.
- chr18:5,956,101–6,017,839, 2 genes, copy number 10: AP001021.2, RNU5F-3P.

Autosomal genes at a single copy (total copy number 1): 595. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
